Somatic mutation profile of tumor specimen 1105198 (aliquot 7316UP-2837-1105198) from CPTAC case C1230738, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen 1105198: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec9eff91-baf9-475a-8032-a35d7149cc6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105281 (Blood Derived Normal), aliquot 7316UP-2837-1105281; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d6c4b60-a4f1-46df-97d1-557e07c2059a

The open-access MAF lists 64 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Intron 4, Nonsense Mutation 3, RNA 2, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 306/337 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; called by muse, mutect2, varscan2
- ABCA10 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 89/99 reads (90%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1362810033; called by muse, mutect2, varscan2
- ANKRD50 | c.3991A>T p.M1331L | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs200657431; called by muse, mutect2, varscan2
- CC2D1A | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769765974; called by muse, mutect2, varscan2
- CCDC146 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs780800729; called by muse, mutect2
- CROCC | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1249043016; called by muse, mutect2, varscan2
- CSH2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 336/380 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775328717, COSV61080906; called by muse, mutect2, varscan2
- FBXW11 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 76/170 reads (45%) | catalogued as rs995419585, COSV51605516; called by muse, mutect2, varscan2
- FCGBP | c.12073C>T p.R4025W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs746046430; called by muse, mutect2, varscan2
- GRIP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 110/275 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs377476830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLC7 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 391/467 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs373815473; called by muse, mutect2, varscan2
- KLF14 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 36/734 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554470860; called by muse, mutect2
- KRT18 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs1217770008; called by muse, mutect2, varscan2
- LCE3A | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 223/506 reads (44%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1469550473, COSV59551162; called by muse, mutect2, varscan2
- MUC16 | c.3904G>A p.G1302R | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV67496618; called by muse, mutect2, varscan2
- NEURL1 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 237/269 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV63914659; called by muse, mutect2, varscan2
- PLXNB2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as rs1377601683; called by muse, mutect2, varscan2
- PTPRQ | c.1934C>T p.T645M (on ENST00000616559; = p.T603M on NM_001145026.2) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs924539666; called by muse, mutect2, varscan2
- RIMS2 | c.1223G>A p.R408Q (on ENST00000666250 / NM_001348490.2; = p.R216Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs376489252, COSV51663807; called by muse, mutect2, varscan2
- SERPINB11 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369601900; called by muse, mutect2, varscan2
- SNX2 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV101075820; called by muse, mutect2, varscan2
- TBC1D17 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs899321303; called by muse, mutect2, varscan2
- ZNF99 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV68054631; called by muse, mutect2, varscan2
- ADAMTS16 | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRICD5 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BTNL8 | c.397+2T>A p.X133_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | called by muse, varscan2
- CSMD3 | c.2053G>A p.V685I (on ENST00000297405 / NM_001363185.1; = p.V581I on NM_052900.3) | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CUL2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DOP1A | c.2237C>A p.A746D | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1958 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRGPRF | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MRGPRX1 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOP56 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR51S1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.752); called by muse, mutect2
- PKHD1L1 | c.12298C>T p.Q4100* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- RUNX1 | c.1270G>A p.D424N (on ENST00000344691 / NM_001001890.3; = p.D451N on NM_001754.5) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- SV2C | c.1593C>A p.Y531* | Nonsense Mutation (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- TAPBP | c.1033G>C p.G345R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR97 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 157/341 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB7A | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADGRD1 | c.1551C>T p.S517= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs1325779017, COSV55450141; called by muse, mutect2, varscan2
- AGO2 | c.1440C>T p.D480= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as rs148281188; called by muse, mutect2, varscan2
- CCDC144A | c.222C>T p.H74= | Silent (SNP) | VAF 121/340 reads (36%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.804A>G p.Q268= | Silent (SNP) | VAF 56/209 reads (27%) | catalogued as rs377098745, COSV50407482; called by muse, mutect2, varscan2
- CXorf65 | c.42G>T p.L14= | Silent (SNP) | VAF 93/212 reads (44%) | called by muse, mutect2, varscan2
- FAM149A | c.1365A>T p.A455= (on ENST00000356371 / NM_001367768.2; = p.A164= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 124/265 reads (47%) | called by muse, mutect2, varscan2
- GRPR | c.654C>T p.F218= | Silent (SNP) | VAF 35/463 reads (8%) | called by muse, mutect2
- OR3A2 | c.561C>T p.Y187= | Silent (SNP) | VAF 43/452 reads (10%) | called by muse, mutect2, varscan2
- PAN2 | c.312C>T p.A104= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- PDP1 | c.276T>C p.N92= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs766927852; called by muse, mutect2, varscan2
- SLC28A3 | c.1068C>A p.T356= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- SLFN5 | c.2637G>A p.R879= | Silent (SNP) | VAF 67/77 reads (87%) | called by muse, mutect2, varscan2
- TEX11 | c.1470C>T p.N490= (on ENST00000344304; = p.N475= on NM_031276.3) | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as rs1168415970, COSV60234072; called by muse, mutect2, varscan2
- WARS2 | c.549C>A p.V183= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- ZAP70 | c.1752C>T p.P584= | Silent (SNP) | VAF 108/175 reads (62%) | catalogued as rs199627332; called by muse, mutect2, varscan2
- ZNF99 | c.813C>A p.T271= | Silent (SNP) | VAF 75/165 reads (45%) | catalogued as COSV68055425; called by muse, mutect2, varscan2
- ADAM1A | n.1721C>A | RNA (SNP) | VAF 73/412 reads (18%) | called by muse, mutect2, varscan2
- CRPPA | c.*2313C>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs751996181; ClinVar: uncertain significance; called by muse, varscan2
- CYP21A2 | c.203-27G>A | Intron (SNP) | VAF 40/203 reads (20%) | catalogued as rs538722250; called by mutect2, varscan2
- MRRFP1 | n.341A>G | RNA (SNP) | VAF 84/178 reads (47%) | called by muse, mutect2, varscan2
- NKD2 | c.-11T>G | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- POLA1 | c.2947-20982C>A | Intron (SNP) | VAF 33/572 reads (6%) | called by muse, mutect2
- PRKG1 | c.935+18995A>C | Intron (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- TINAG | c.624+23G>A | Intron (SNP) | VAF 28/171 reads (16%) | catalogued as rs752360078; called by muse, mutect2, varscan2
